Somatic mutation profile of tumor specimen C3L-04759-02 (aliquot CPT0249890007) from CPTAC case C3L-04759, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.8 years (24,773 days).
Specimen C3L-04759-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82e2f7f2-5eb7-4bd0-8d2e-16019d57dc25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04759-31 (Blood Derived Normal), aliquot CPT0250040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/682c637a-6202-4550-a8d3-762f73c48480

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Splice Site 2, 5'UTR 1, Intron 1, Nonsense Mutation 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 120/548 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 35/202 reads (17%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- BICRAL | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396545244; called by muse, mutect2, varscan2
- KRTAP15-1 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); catalogued as rs907156855; called by muse, mutect2, varscan2
- MYO18A | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62863594, COSV62872643; called by muse, mutect2, varscan2
- NCOR2 | c.4846C>T p.R1616W | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs944324049; called by muse, mutect2
- PCDHGA4 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs571571659, COSV53962823; called by muse, mutect2
- SPEN | c.4150G>A p.E1384K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs764593579; called by muse, mutect2, varscan2
- ZNF687 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1006862537, COSV99649346; called by muse, mutect2
- ZNF746 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 33/419 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs564867784, COSV61407497; called by muse, mutect2
- AC069544.2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- AHNAK | c.16145G>A p.C5382Y | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANGPT1 | c.614A>C p.H205P | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- BPNT1 | c.370_382+4del p.X124_splice | Splice Site (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- CBS | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, varscan2
- CCP110 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CD59 | c.254C>G p.T85R | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- DMRTB1 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EFCAB6 | c.2314C>A p.H772N | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- HOXD11 | c.905T>C p.M302T | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- KLHL29 | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- LAMB1 | c.287T>A p.I96N | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MED12 | c.3616C>G p.H1206D | Missense Mutation (SNP) | VAF 55/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MRPL30 | c.279+1G>C p.X93_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- OTUB1 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA4 | c.1867G>T p.V623L | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDILT | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 4/93 reads (4%) | called by muse, mutect2
- RBBP4 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ZNF513 | c.1339A>G p.S447G | Missense Mutation (SNP) | VAF 45/497 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2
- ZNF99 | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 11/433 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- CSMD3 | c.8748G>A p.Q2916= (on ENST00000297405 / NM_001363185.1; = p.Q2747= on NM_052900.3) | Silent (SNP) | VAF 30/320 reads (9%) | catalogued as COSV52289672; called by muse, mutect2
- CXCR4 | c.855C>T p.S285= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- DENND5B | c.2424A>G p.Q808= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs765356750; called by muse, mutect2, varscan2
- IDH1 | c.543G>C p.G181= | Silent (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- OR11H2 | c.417C>A p.I139= (on ENST00000556246; = p.I150= on NM_001197287.1) | Silent (SNP) | VAF 50/433 reads (12%) | called by muse, mutect2, varscan2
- TPR | c.6994T>C p.L2332= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- TPRG1 | c.472C>T p.L158= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- C19orf12 | chr19:29700938 T>A | 3'Flank (SNP) | VAF 28/182 reads (15%) | called by muse, mutect2, varscan2
- SOX6 | c.-5+132G>A | Intron (SNP) | VAF 14/148 reads (9%) | catalogued as rs1378256335; called by muse, mutect2, varscan2
- TENT5B | c.-4G>A | 5'UTR (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
